Gene-level copy-number profile of tumor specimen TCGA-28-5209-01A from TCGA case TCGA-28-5209, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.7 years (24,362 days).
Specimen TCGA-28-5209-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.069effeb-0751-47d7-9b3a-554e9dcef494.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-28-5209-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f27a2d8-2b37-4616-9f1f-536cf7451b72

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 5,260; copy number 2: 48,532; copy number 3: 5,856; copy number 8: 49; copy number 12: 2; copy number 13: 3; copy number 32: 64; copy number 33: 3; copy number 38: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-28-5209-01A-01D-1479-01): tumor purity 0.92, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,367,424–22,214,672, 32 genes: IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 134 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,185,071–56,687,366, 85 genes, copy number 12–38 (within-gene range 11–38) (broad region; genes not listed).
- chr12:48,688,458–48,999,375, 22 genes, copy number 8 (within-gene range 2–8): CCNT1, TEX49, AC117498.1, ADCY6, MIR4701, ADCY6-DT, AC117498.2, Y_RNA, CACNB3, DDX23, RND1, RNU6-600P, AC073610.1, AC073610.2, CCDC65, FKBP11, ARF3, WNT10B, RNU6-940P, WNT1, DDN, AC011603.3.
- chr12:57,693,955–57,984,761, 27 genes, copy number 8 (within-gene range 2–8): OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.

Autosomal genes at a single copy (total copy number 1): 4,592. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
